Somatic mutation profile of tumor specimen MMRF_1630_1_BM_CD138pos (aliquot MMRF_1630_1_BM_CD138pos_T1_KBS5U_L04306) from MMRF case MMRF_1630, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.2 years (21,613 days).
Specimen MMRF_1630_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9dd8b55-c546-47e0-a989-41eb42b6733d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1630_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1630_2_PB_Whole_C1_KBS5U_L04317; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb229307-c8bf-4b46-a0dd-3d80d33ce041

The open-access MAF lists 104 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 25, Silent 14, Intron 10, 5'UTR 5, Nonsense Mutation 4, 3'Flank 3, RNA 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>A p.G509E (on ENST00000288602 / NM_001374244.1; = p.G469E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- OPN1LW | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 78/192 reads (41%) | catalogued as rs104894912, CM931121; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPL10L | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 35/78 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV53558657, COSV53559010, COSV53561078; called by muse, mutect2, varscan2
- AP3B2 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs1033207460; called by muse, mutect2, varscan2
- ARHGEF1 | c.2084C>T p.T695M | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs782573860; called by muse, mutect2, varscan2
- CAPSL | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748659530, COSV68439781; called by muse, mutect2, varscan2
- CSPP1 | c.1526C>T p.S509L (on ENST00000676605; = p.S468L on NM_024790.6) | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV51593796; called by muse, mutect2, varscan2
- DNAH10 | c.10758C>G p.Y3586* (on ENST00000409039; = p.Y3525* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | catalogued as COSV68991015; called by muse, mutect2, varscan2
- HMX3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV100774172; called by muse, mutect2
- IGHV2-5 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.68); catalogued as rs552563635; called by muse, mutect2, varscan2
- IGLV4-69 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778427118; called by muse, varscan2
- KBTBD7 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs560790512; called by muse, mutect2, varscan2
- KCNIP2 | c.520C>T p.R174W (on ENST00000356640 / NM_173191.3; = p.R189W on NM_014591.5) | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398216871, COSV53306090; called by muse, mutect2, varscan2
- KLHL36 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs763651100; called by muse, mutect2
- KRTAP10-1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs782420165; called by muse, mutect2, varscan2
- LTB | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 101/203 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100272147, COSV59864787; called by muse, mutect2
- MYT1L | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 78/127 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV67731657; called by muse, mutect2, varscan2
- NOX4 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.457); catalogued as COSV54454496; called by muse, mutect2, varscan2
- PIEZO2 | c.4667C>T p.T1556M | Missense Mutation (SNP) | VAF 105/214 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs181523658; called by muse, mutect2, varscan2
- PNLIPRP3 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV65049427; called by muse, mutect2, varscan2
- SEMA6B | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367818275; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3538G>T p.E1180* | Nonsense Mutation (SNP) | VAF 46/144 reads (32%) | catalogued as COSV54437463; called by muse, mutect2, varscan2
- WT1 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.2); catalogued as CM041869, COSV60066810, COSV60071867; called by muse, mutect2, varscan2
- AFM | c.153T>A p.F51L | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CAPSL | c.155A>T p.D52V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDCA5 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- COL4A4 | c.3721C>G p.P1241A | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EDEM3 | c.2366T>A p.L789H | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FAM71B | c.1078A>G p.M360V | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRR3 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 107/306 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GNA14 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- H1-3 | c.275_288del p.G92Dfs*34 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | called by mutect2, pindel, varscan2
- H2AC15 | c.293_294del p.L98Rfs*2 | Frame Shift Del (DEL) | VAF 53/113 reads (47%) | called by mutect2, pindel, varscan2
- HERC6 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- INHBB | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KNDC1 | c.3580-1G>T p.X1194_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- LRRC40 | c.86A>T p.Q29L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MECOM | c.1322T>C p.L441P (on ENST00000468789 / NM_001105078.4; = p.L629P on NM_004991.4) | Missense Mutation (SNP) | VAF 120/189 reads (63%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PKD1L1 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLXND1 | c.4995G>A p.V1665= | Splice Region (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2
- PP2D1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKACB | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- SPATA2L | c.106T>C p.W36R | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (1); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- TENT5C | c.760_761insC p.D254Afs*30 | Frame Shift Ins (INS) | VAF 45/122 reads (37%) | called by mutect2, pindel, varscan2
- TLE4 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ABCA9 | c.504T>C p.C168= | Silent (SNP) | VAF 65/155 reads (42%) | called by muse, mutect2, varscan2
- AK9 | c.4587G>A p.E1529= | Silent (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- BMP7 | c.1242C>T p.N414= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs578072951; called by muse, mutect2, varscan2
- CCT8L2 | c.1638T>G p.P546= | Silent (SNP) | VAF 142/284 reads (50%) | called by muse, mutect2, varscan2
- CIB2 | c.96G>A p.S32= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs541843030, COSV51948960; called by muse, mutect2, varscan2
- DDB2 | c.774G>A p.L258= | Silent (SNP) | VAF 62/121 reads (51%) | called by muse, mutect2, varscan2
- EGR1 | c.1548A>T p.S516= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- EIF3L | c.870C>T p.A290= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as rs553376364; called by muse, mutect2, varscan2
- FRMD8 | c.1371C>T p.P457= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs529038057; called by muse, mutect2, varscan2
- FUBP3 | c.390C>G p.T130= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- MCM2 | c.570C>T p.G190= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as rs773248578; called by muse, mutect2, varscan2
- PTCH2 | c.831C>T p.H277= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs909568880; called by muse, mutect2, varscan2
- YAP1 | c.363G>A p.Q121= | Silent (SNP) | VAF 52/66 reads (79%) | catalogued as COSV56772756, COSV99176038; called by muse, mutect2, varscan2
- ZNF837 | c.222C>T p.P74= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1325537449; called by muse, mutect2, varscan2
- ABHD6 | c.-10A>G | 5'UTR (SNP) | VAF 90/313 reads (29%) | called by muse, mutect2, varscan2
- ACTN1 | c.105+755T>C | Intron (SNP) | VAF 103/216 reads (48%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3102-10A>C | Intron (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- AL359555.4 | n.494G>A | RNA (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- ATP13A3 | c.*398G>A | 3'UTR (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- BBS7 | c.*494T>C | 3'UTR (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- C8orf33 | c.*213_*214del | 3'UTR (DEL) | VAF 37/92 reads (40%) | called by mutect2, pindel, varscan2
- CHL1 | chr3:407885 G>A | 3'Flank (SNP) | VAF 53/147 reads (36%) | called by muse, mutect2, varscan2
- CHORDC1 | c.564-286C>T | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- CHRDL1 | c.*152G>T | 3'UTR (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- CTBP2P4 | n.898G>A | RNA (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- DNAJC10 | c.*11598A>T | 3'UTR (SNP) | VAF 92/232 reads (40%) | called by muse, mutect2, varscan2
- ECE2 | c.1973-53C>G | Intron (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- ERICH1 | c.1258+1403G>A | Intron (SNP) | VAF 10/359 reads (3%) | called by muse, mutect2
- FBXO21 | chr12:117143778 C>T | 3'Flank (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- FOXK1 | c.*7376_*7377del | 3'UTR (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- FRMD4A | c.46-149438C>T | Intron (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- FRRS1L | c.710-73C>G | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- IGLC2 | c.*141A>G | 3'UTR (SNP) | VAF 19/101 reads (19%) | catalogued as rs557150823; called by muse, mutect2, varscan2
- IL7R | c.*1712C>G | 3'UTR (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- IRAK3 | c.134-6686G>T | Intron (SNP) | VAF 140/298 reads (47%) | catalogued as rs1027048442; called by muse, mutect2, varscan2
- LANCL1 | chr2:210432322 T>C | 3'Flank (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- LRRC4 | c.*10C>T | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- MEOX2 | c.*512C>G | 3'UTR (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
- MFAP3L | c.*1711C>T | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- NDUFA5 | c.21+106G>T | Intron (SNP) | VAF 193/368 reads (52%) | called by muse, mutect2, varscan2
- NDUFC2 | c.*1033G>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- NFE2L3 | c.-203G>T | 5'UTR (SNP) | VAF 6/8 reads (75%) | catalogued as rs1399307628; called by muse, mutect2, varscan2
- NHS | c.*2304A>G | 3'UTR (SNP) | VAF 36/37 reads (97%) | called by muse, mutect2, varscan2
- NSFL1C | c.-68G>A | 5'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- PKNOX2 | c.*1298C>A | 3'UTR (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- RBM33 | c.*6074A>G | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- SELENOI | c.*6561T>C | 3'UTR (SNP) | VAF 30/68 reads (44%) | catalogued as rs933525426; called by muse, mutect2, varscan2
- SH3BGRL2 | c.*1938G>A | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- SLC25A37 | c.*1933G>A | 3'UTR (SNP) | VAF 107/198 reads (54%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*1698G>T | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- SNX10 | c.*979G>A | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-4208G>A | Intron (SNP) | VAF 78/167 reads (47%) | catalogued as rs908692469; called by muse, mutect2, varscan2
- THBD | c.*1779G>A | 3'UTR (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1002T>C | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- USP28 | c.*1184T>C | 3'UTR (SNP) | VAF 21/42 reads (50%) | called by muse, varscan2
- USP28 | c.*1100T>C | 3'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, varscan2
- WDR36 | c.*1884G>A | 3'UTR (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- WHAMM | c.-30C>G | 5'UTR (SNP) | VAF 42/65 reads (65%) | called by muse, mutect2, varscan2
- ZFAT | c.-71C>T | 5'UTR (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
